Somatic mutation profile of tumor specimen TCGA-DJ-A13T-01A (aliquot TCGA-DJ-A13T-01A-11D-A10S-08) from TCGA case TCGA-DJ-A13T, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 37.4 years (13,668 days).
Specimen TCGA-DJ-A13T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a542185-7d08-4238-9560-fa61defd184f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A13T-10A (Blood Derived Normal), aliquot TCGA-DJ-A13T-10A-01D-A10S-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/27b81103-1a1b-42be-b660-17d5ec7dee62

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- HPD | c.334G>A p.E112K | Missense Mutation (SNP) | VAF 56/125 reads (45%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.572); catalogued as COSV56642590; called by muse, mutect2, varscan2
- SLC38A4 | c.1222T>A p.L408I | Missense Mutation (SNP) | VAF 64/163 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV56968937; called by muse, mutect2, varscan2
- ZNF607 | c.347G>T p.C116F | Missense Mutation (SNP) | VAF 93/240 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV62205688; called by muse, mutect2, varscan2
